Somatic mutation profile of tumor specimen MMRF_1921_1_BM_CD138pos (aliquot MMRF_1921_1_BM_CD138pos_T1_KBS5U_L06429) from MMRF case MMRF_1921, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.7 years (22,546 days).
Specimen MMRF_1921_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cce5074-4cba-45fe-946e-1a73e59e2394.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1921_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1921_1_PB_Whole_C3_KBS5U_L06474; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c31f6351-d7a6-4007-9b1c-d4b73d40720d

The open-access MAF lists 82 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 22, Silent 10, 5'UTR 6, Intron 4, Nonsense Mutation 3, Splice Site 2, RNA 2, Frame Shift Del 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MYO15A | c.9572G>A p.R3191H | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373520843, CM1513046; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCB1 | c.992G>A p.R331H (on ENST00000263121; = p.R377H on NM_003073.5) | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs387906812, CM122478, COSV51954090, COSV51954233, COSV51954740; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ARHGAP15 | c.703+3_703+6del p.X235_splice | Splice Site (DEL) | VAF 8/33 reads (24%) | catalogued as rs778931663; called by mutect2, pindel
- CCDC137 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs1036493982, COSV61303773; called by muse, mutect2
- CPNE7 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs747514745, COSV99255208; called by muse, mutect2, varscan2
- ERBB2 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs759579850; called by muse, mutect2
- FBN3 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs193095701; called by muse, mutect2, varscan2
- GCK | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs778550411, CM020442, COSV60786376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H4C8 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751532587, COSV56804750; called by muse, mutect2, varscan2
- IGHV2-70 | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs371469802; called by muse, varscan2
- LCOR | c.3047C>T p.S1016L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs759673171, COSV53714802, COSV53718328; called by muse, mutect2, varscan2
- MTMR4 | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV100051367; called by muse, mutect2, varscan2
- OBP2B | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs376819822; called by mutect2, varscan2
- OBSL1 | c.4940C>T p.T1647M | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs771909036; called by muse, mutect2
- OR10Q1 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1464228910, COSV57469614; called by muse, mutect2, varscan2
- PCDH7 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV62338510; called by muse, mutect2
- PHKB | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143421326; called by muse, mutect2, varscan2
- SALL3 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1475797062, COSV101609958, COSV73305909; called by muse, mutect2, varscan2
- SGK1 | c.77-1G>A p.X26_splice | Splice Site (SNP) | VAF 86/192 reads (45%) | catalogued as rs186450029, COSV52804758; called by muse, mutect2, varscan2
- SLIRP | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs779231938; called by muse, mutect2, varscan2
- TLN2 | c.3607A>C p.N1203H | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV60888000; called by muse, mutect2, varscan2
- ARHGAP32 | c.3553G>T p.D1185Y (on ENST00000310343 / NM_001378025.1; = p.D836Y on NM_014715.4) | Missense Mutation (SNP) | VAF 115/358 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- EPB41L3 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- MFHAS1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by mutect2, varscan2
- NR2F1 | c.950C>G p.A317G | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PPFIBP1 | c.2735A>T p.N912I (on ENST00000318304 / NM_177444.3; = p.N906I on NM_003622.4) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PPWD1 | c.124A>G p.N42D | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBBP7 | c.668del p.T223Mfs*7 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- RBM15B | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC6A1 | c.397del p.S133Hfs*4 | Frame Shift Del (DEL) | VAF 25/112 reads (22%) | called by mutect2, pindel, varscan2
- SYNE2 | c.15864A>C p.E5288D | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TBC1D14 | c.1758G>A p.W586* | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- TBC1D14 | c.1759A>C p.I587L | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TTYH2 | c.1525T>A p.Y509N | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- UBQLN2 | c.1394T>G p.L465* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.2691A>C p.R897= | Silent (SNP) | VAF 50/116 reads (43%) | called by muse, mutect2, varscan2
- C11orf16 | c.300G>A p.R100= | Silent (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- DDX60 | c.2127T>C p.S709= | Silent (SNP) | VAF 38/65 reads (58%) | called by muse, mutect2, varscan2
- EFS | c.1002C>T p.D334= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- FOXG1 | c.1107C>T p.N369= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as rs747996412, COSV57396863; called by muse, mutect2, varscan2
- IGHV2-70 | c.252G>T p.L84= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs374732396; called by muse, varscan2
- IGKV1-5 | c.96C>G p.T32= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs760716952; called by muse, varscan2
- KSR2 | c.783G>A p.P261= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as rs778155102, COSV60387410; called by muse, mutect2, varscan2
- MFHAS1 | c.108C>A p.A36= | Silent (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- SLC22A2 | c.99C>T p.F33= | Silent (SNP) | VAF 75/152 reads (49%) | catalogued as rs568261775, COSV65268498; called by muse, mutect2, varscan2
- AC019294.1 | n.217G>A | RNA (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.-187C>T | 5'UTR (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- ATM | c.*2245A>C | 3'UTR (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- CALN1 | c.*7856A>G | 3'UTR (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- CEP85L | c.-133A>C | 5'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.*140C>T | 3'UTR (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- EPHA7 | c.*1358A>G | 3'UTR (SNP) | VAF 36/86 reads (42%) | catalogued as rs1161593936; called by muse, mutect2, varscan2
- EXTL2 | c.*225A>G | 3'UTR (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- FBXO32 | c.*2148T>G | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- FCHO2 | c.*1786del | 3'UTR (DEL) | VAF 39/103 reads (38%) | called by mutect2, pindel, varscan2
- FSTL4 | c.*616T>A | 3'UTR (SNP) | VAF 21/153 reads (14%) | catalogued as rs1007877781; called by muse, varscan2
- GFAP | c.1292-60G>A | Intron (SNP) | VAF 20/56 reads (36%) | called by mutect2, varscan2
- IGHV1-69D | c.-47A>G | 5'UTR (SNP) | VAF 15/40 reads (38%) | called by muse, varscan2
- MAGEC2 | c.*361T>C | 3'UTR (SNP) | VAF 19/24 reads (79%) | called by muse, mutect2, varscan2
- MGLL | c.*2549A>T | 3'UTR (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- NFAM1 | c.*1413del | 3'UTR (DEL) | VAF 27/68 reads (40%) | catalogued as rs1046463704; called by mutect2, varscan2
- PABPC1P2 | n.511G>T | RNA (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- PADI2 | c.*1124A>T | 3'UTR (SNP) | VAF 49/83 reads (59%) | called by muse, mutect2, varscan2
- PCDH17 | c.*2403T>A | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- PLEKHM3 | c.1950+7608C>T | Intron (SNP) | VAF 37/136 reads (27%) | catalogued as rs781240282, COSV66819300; called by muse, mutect2, varscan2
- POU4F2 | c.*548_*549dup | 3'UTR (INS) | VAF 13/88 reads (15%) | catalogued as rs1206379541; called by mutect2, varscan2
- RNF10 | c.2143-1122_2143-1120del | Intron (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- RNF17 | c.-27C>T | 5'UTR (SNP) | VAF 44/86 reads (51%) | catalogued as rs778283189; called by muse, mutect2, varscan2
- SDK2 | c.*1551C>T | 3'UTR (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2, varscan2
- SFT2D2 | c.*198G>T | 3'UTR (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- SLC17A5 | c.*468C>T | 3'UTR (SNP) | VAF 22/49 reads (45%) | catalogued as rs893458360; called by muse, mutect2, varscan2
- SLC6A1 | c.*1102C>T | 3'UTR (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2
- SSTR1 | c.*2339A>G | 3'UTR (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- STX7 | c.*2060_*2069dup | 3'UTR (INS) | VAF 28/84 reads (33%) | called by mutect2, varscan2
- SULT1E1 | c.*507del | 3'UTR (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- TFCP2 | c.-546C>G | 5'UTR (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- TMEM132E | chr17:34575298 C>T | 5'Flank (SNP) | VAF 9/37 reads (24%) | catalogued as rs995542391; called by muse, mutect2, varscan2
- TNFAIP6 | c.*471G>C | 3'UTR (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2
- TSG101 | c.-47G>A | 5'UTR (SNP) | VAF 53/200 reads (27%) | called by muse, mutect2, varscan2
- UBN2 | c.2024+522dup | Intron (INS) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- ZNF774 | chr15:90348875 G>A | 5'Flank (SNP) | VAF 136/317 reads (43%) | called by muse, mutect2, varscan2
